CCDI case PBBMYK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ea39b2af-f502-49a1-9718-9432e795b725

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 10.8 years (3,960 days).

Biospecimens (3 samples)
- Sample 0DELJ2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DELJW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DELKP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
